Somatic mutation profile of tumor specimen MMRF_1678_1_BM_CD138pos (aliquot MMRF_1678_1_BM_CD138pos_T1_KBS5U_L05781) from MMRF case MMRF_1678, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 80.7 years (29,466 days).
Specimen MMRF_1678_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 347731a8-89bd-4ee8-8fa5-8c2fc010f4a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1678_1_PB_WBC (Blood Derived Normal), aliquot MMRF_1678_1_PB_WBC_C3_KBS5U_L05795; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9bbf619c-4740-4395-b3de-b7adc4d3ddbb

The open-access MAF lists 254 somatic variants for this specimen: 110 protein-altering or splice-affecting, 33 silent, 111 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 101, 3'UTR 65, Silent 33, Intron 29, 5'UTR 8, 5'Flank 5, Nonsense Mutation 3, Splice Region 3, 3'Flank 2, Frame Shift Del 2, RNA 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AJAP1 | c.28A>G p.S10G | Missense Mutation (SNP) | VAF 47/207 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs750405906; called by muse, mutect2, varscan2
- ANK1 | c.3469G>A p.D1157N | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs747027965, COSV55895567; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APBA1 | c.1100C>T p.S367L | Missense Mutation (SNP) | VAF 27/216 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55221469; called by muse, mutect2, varscan2
- CBY3 | c.560T>C p.I187T | Missense Mutation (SNP) | VAF 38/307 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs1343160608; called by muse, mutect2, varscan2
- CDH11 | c.184G>A p.V62M | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs556647809, COSV51756679, COSV51758059; called by muse, mutect2, varscan2
- CLU | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as CM124610, COSV57066844; called by muse, mutect2, varscan2
- CPA5 | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs782695307; called by muse, mutect2, varscan2
- CYP3A4 | c.1208G>T p.R403L | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV60501882; called by muse, mutect2, varscan2
- DPRX | c.19C>G p.L7V | Missense Mutation (SNP) | VAF 89/278 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.061); catalogued as COSV100934065; called by muse, mutect2, varscan2
- DYNC2LI1 | c.731+2T>G p.X244_splice | Splice Site (SNP) | VAF 16/55 reads (29%) | catalogued as rs747183698; called by muse, mutect2, varscan2
- EVPL | c.4675C>T p.R1559C | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs761341904; called by muse, mutect2, varscan2
- FAT4 | c.14194A>G p.T4732A | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV58700296; called by muse, mutect2, varscan2
- GABRQ | c.1822G>A p.D608N | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782673532; called by muse, mutect2
- GFRAL | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs868599487, COSV61228767, COSV61234756; called by muse, mutect2, varscan2
- IGHV2-5 | c.304A>T p.T102S | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated (0.29); PolyPhen benign (0.062); catalogued as rs531628292; called by muse, mutect2
- IGHV2-5 | c.211C>A p.L71I | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs115014976; called by muse, varscan2
- IGHV2-5 | c.65C>G p.T22S | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.215); catalogued as rs1555425631; called by muse, varscan2
- KIN | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 59/225 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as COSV59622963; called by muse, mutect2, varscan2
- LAMB2 | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM082911; called by muse, mutect2, varscan2
- LARP6 | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs761513596; called by muse, mutect2, varscan2
- MALRD1 | c.6207C>A p.Y2069* | Nonsense Mutation (SNP) | VAF 18/126 reads (14%) | catalogued as COSV65975727; called by muse, mutect2, varscan2
- N4BP2L2 | c.2102C>T p.S701F (on ENST00000674422; = p.S272F on NM_033111.4) | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.188); catalogued as COSV62631778; called by muse, mutect2, varscan2
- NEDD1 | c.1384C>G p.L462V | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as rs767486150; called by muse, mutect2, varscan2
- OR6P1 | c.166C>T p.H56Y | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.67); catalogued as rs866035897; called by muse, mutect2, varscan2
- PARD3 | c.689G>A p.G230D | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1246051371; called by muse, mutect2, varscan2
- PCF11 | c.3341C>T p.T1114I | Missense Mutation (SNP) | VAF 34/181 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV53530847; called by muse, mutect2, varscan2
- PCIF1 | c.596C>A p.P199H | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65026467; called by muse, mutect2, varscan2
- PTPRS | c.4279G>A p.A1427T | Missense Mutation (SNP) | VAF 31/195 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs114545401; called by muse, mutect2, varscan2
- PTPRS | c.2431G>A p.A811T | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as rs1340374850, COSV53639395; called by muse, mutect2, varscan2
- SDR42E1 | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.472); catalogued as rs1232292416, COSV61094535; called by muse, mutect2, varscan2
- SEC22A | c.314C>T p.T105I | Missense Mutation (SNP) | VAF 46/345 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.398); catalogued as rs757884914; called by muse, mutect2, varscan2
- SLC25A22 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV57192915; called by muse, mutect2, varscan2
- SLC25A45 | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199845843; called by muse, mutect2, varscan2
- TAF7L | c.826G>A p.V276I | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.011); catalogued as COSV61256291; called by muse, mutect2
- TBL1XR1 | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV101467747; called by muse, mutect2, varscan2
- TRIM61 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 8/161 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as COSV61417700; called by muse, mutect2
- UHRF1BP1L | c.2762G>A p.R921K | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs758097896, COSV54435816; called by muse, mutect2, varscan2
- YARS2 | c.160G>C p.E54Q | Missense Mutation (SNP) | VAF 23/177 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs982062360; called by muse, mutect2, varscan2
- ZNF107 | c.1229A>G p.K410R | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); catalogued as rs1413346485; called by muse, mutect2, varscan2
- ZNF211 | c.980G>A p.S327N (on ENST00000347302 / NM_198855.4; = p.S340N on NM_006385.5) | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT tolerated (0.8); PolyPhen benign (0.022); catalogued as COSV53741331; called by muse, mutect2, varscan2
- ZNF365 | c.1196del p.K399Sfs*6 | Frame Shift Del (DEL) | VAF 16/34 reads (47%) | catalogued as rs751774089; called by mutect2, varscan2
- ABCB9 | c.623A>G p.Y208C | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- ABCC12 | c.474A>T p.K158N | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AC097637.1 | c.221A>T p.E74V | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- AP2B1 | c.515C>G p.S172* | Nonsense Mutation (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- ARHGAP5 | c.958T>G p.S320A | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BEND5 | c.567C>A p.N189K | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- C6orf118 | c.252C>A p.H84Q | Missense Mutation (SNP) | VAF 13/168 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.007); called by muse, mutect2
- CACNB2 | c.57G>T p.Q19H | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- CCDC182 | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CEP83 | c.536A>T p.K179I | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- CES4A | c.405G>C p.V135= | Splice Region (SNP) | VAF 19/81 reads (23%) | called by muse, mutect2, varscan2
- CLU | c.1157T>A p.V386D | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- CNTN3 | c.2029G>A p.A677T | Missense Mutation (SNP) | VAF 17/177 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CREB3L3 | c.576G>T p.L192= | Splice Region (SNP) | VAF 6/53 reads (11%) | called by muse, mutect2
- CYLD | c.2362T>G p.C788G | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DHRS7B | c.17C>T p.T6I | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EIF2AK2 | c.527A>G p.Y176C | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- FMR1 | c.1664A>T p.D555V | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- GAS2 | c.10G>T p.A4S | Missense Mutation (SNP) | VAF 80/205 reads (39%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); called by muse, mutect2
- GCC1 | c.1159G>A p.D387N | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- GFI1B | c.523C>A p.P175T | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.265); called by muse, mutect2
- GLRA3 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); called by muse, mutect2
- HCFC2 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- HPR | c.136G>C p.E46Q | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.998); called by muse, varscan2
- HSPG2 | c.9533C>A p.S3178* | Nonsense Mutation (SNP) | VAF 12/82 reads (15%) | called by muse, mutect2, varscan2
- IGHV2-70D | c.134G>C p.G45A | Missense Mutation (SNP) | VAF 32/37 reads (86%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IL20RA | c.1061A>C p.E354A | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- IQSEC2 | c.1564G>A p.D522N (on ENST00000642864 / NM_001111125.3; = p.D317N on NM_015075.2) | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- IRF8 | c.790A>T p.R264W | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ITGAM | c.2866T>C p.Y956H (on ENST00000648685 / NM_001145808.2; = p.Y955H on NM_000632.4) | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ITPRID1 | c.164-3T>C | Splice Region (SNP) | VAF 22/96 reads (23%) | called by muse, mutect2, varscan2
- KIF26B | c.1972G>A p.D658N | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KRTAP19-3 | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- MACF1 | c.7127G>A p.S2376N | Missense Mutation (SNP) | VAF 21/150 reads (14%) | called by muse, mutect2, varscan2
- MGA | c.2345G>T p.R782M | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MICAL3 | c.2500G>C p.A834P | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MICU3 | c.701A>G p.H234R | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.402); called by muse, mutect2, varscan2
- MPDU1 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MPP7 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- NCAPG | c.2092G>A p.D698N | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.076); called by muse, mutect2
- NDST4 | c.2538T>A p.N846K | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NUP160 | c.4022A>G p.Y1341C | Missense Mutation (SNP) | VAF 5/120 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- PKD2L2 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 41/265 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PNPLA7 | c.2952G>C p.K984N | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- PPARG | c.122C>A p.T41N (on ENST00000287820 / NM_015869.5; = p.T11N on NM_005037.7) | Missense Mutation (SNP) | VAF 60/313 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- PPP4C | c.608C>T p.T203I | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRKDC | c.11795T>C p.M3932T | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PRKDC | c.7168C>T p.H2390Y | Missense Mutation (SNP) | VAF 7/194 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.288); called by muse, mutect2
- PRR16 | c.854C>T p.P285L (on ENST00000407149 / NM_001300783.2; = p.P262L on NM_016644.2) | Missense Mutation (SNP) | VAF 79/369 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RFX4 | c.1777C>T p.P593S (on ENST00000392842 / NM_213594.3; = p.P499S on NM_032491.6) | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- RNASE1 | c.189G>A p.M63I | Missense Mutation (SNP) | VAF 73/170 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- RNGTT | c.1397_1398del p.S466Cfs*29 | Frame Shift Del (DEL) | VAF 11/36 reads (31%) | called by mutect2, pindel, varscan2
- SACS | c.6165G>T p.Q2055H | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- SDK1 | c.450C>G p.S150R | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- SH2D7 | c.808G>A p.G270S | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SPTAN1 | c.3275A>G p.K1092R | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- STK36 | c.3821G>T p.G1274V | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- SVIL | c.3163G>A p.A1055T (on ENST00000355867 / NM_021738.3; = p.A629T on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TARDBP | c.210T>G p.N70K | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.011); called by muse, mutect2
- TENM2 | c.6830T>G p.I2277S (on ENST00000518659 / NM_001122679.2; = p.I2038S on NM_001080428.3) | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- TEX44 | c.1179C>G p.N393K | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- TEX44 | c.1180T>A p.Y394N | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- TGM5 | c.1228G>A p.G410R (on ENST00000220420 / NM_201631.4; = p.G328R on NM_004245.4) | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TOP2B | c.4327G>T p.D1443Y (on ENST00000264331 / NM_001330700.2; = p.D1438Y on NM_001068.3) | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- USP53 | c.1459C>T p.H487Y | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- VSIG10L | c.1661T>C p.L554P | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- ZBTB14 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 31/201 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF780A | c.537T>A p.N179K | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ZNF804B | c.1424G>A p.C475Y | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ACSBG1 | c.1443C>A p.G481= | Silent (SNP) | VAF 12/65 reads (18%) | called by muse, mutect2, varscan2
- ADGRF2 | c.1641C>T p.I547= (on ENST00000296862 / NM_001368115.2; = p.I479= on NM_153839.7) | Silent (SNP) | VAF 16/108 reads (15%) | called by muse, mutect2, varscan2
- ADH1C | c.744G>A p.K248= | Silent (SNP) | VAF 9/253 reads (4%) | catalogued as COSV72463375; called by muse, mutect2
- CAMK1G | c.381C>A p.V127= | Silent (SNP) | VAF 17/101 reads (17%) | catalogued as rs1299990691; called by muse, mutect2, varscan2
- FASN | c.2652C>T p.V884= | Silent (SNP) | VAF 19/102 reads (19%) | called by muse, mutect2, varscan2
- FIG4 | c.1953C>T p.I651= | Silent (SNP) | VAF 10/146 reads (7%) | catalogued as COSV57785646; called by muse, mutect2
- FMR1 | c.570G>A p.R190= | Silent (SNP) | VAF 23/165 reads (14%) | called by muse, mutect2, varscan2
- GPR149 | c.1017G>A p.Q339= | Silent (SNP) | VAF 22/136 reads (16%) | called by muse, mutect2, varscan2
- GRIN2B | c.2637G>A p.E879= | Silent (SNP) | VAF 48/91 reads (53%) | catalogued as rs200754384; called by muse, mutect2, varscan2
- IGHV2-5 | c.306A>C p.T102= | Silent (SNP) | VAF 24/41 reads (59%) | called by muse, mutect2
- KCNK3 | c.876C>T p.G292= | Silent (SNP) | VAF 12/73 reads (16%) | called by muse, mutect2, varscan2
- KIF16B | c.1603C>T p.L535= | Silent (SNP) | VAF 7/82 reads (9%) | called by muse, mutect2
- KIF19 | c.762A>G p.S254= | Silent (SNP) | VAF 11/24 reads (46%) | called by muse, mutect2, varscan2
- LHX2 | c.150C>T p.A50= | Silent (SNP) | VAF 43/78 reads (55%) | catalogued as rs569497533, COSV65318356; called by muse, mutect2, varscan2
- LRP1 | c.8775C>T p.N2925= | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as rs139174222; called by muse, mutect2, varscan2
- LRP1 | c.10533T>A p.R3511= | Silent (SNP) | VAF 32/132 reads (24%) | called by muse, mutect2, varscan2
- MAP3K10 | c.948T>A p.A316= | Silent (SNP) | VAF 14/81 reads (17%) | called by muse, mutect2, varscan2
- MAPT | c.1896G>A p.K632= (on ENST00000262410 / NM_001377265.1; = p.K240= on NM_005910.5) | Silent (SNP) | VAF 8/173 reads (5%) | called by muse, mutect2
- NALCN | c.3078A>G p.T1026= | Silent (SNP) | VAF 34/88 reads (39%) | called by muse, mutect2, varscan2
- OR12D3 | c.87C>T p.F29= | Silent (SNP) | VAF 33/273 reads (12%) | called by muse, mutect2, varscan2
- OR2M2 | c.171C>A p.T57= | Silent (SNP) | VAF 20/136 reads (15%) | catalogued as rs1558246264, COSV62898141; called by muse, mutect2, varscan2
- PCDHA11 | c.1809C>T p.N603= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as rs1554164817, COSV56518234; called by muse, mutect2, varscan2
- PIWIL4 | c.207C>T p.F69= | Silent (SNP) | VAF 44/204 reads (22%) | called by muse, mutect2, varscan2
- PLEKHA5 | c.495T>C p.N165= | Silent (SNP) | VAF 20/69 reads (29%) | called by muse, mutect2, varscan2
- POM121L12 | c.21C>A p.A7= | Silent (SNP) | VAF 8/90 reads (9%) | catalogued as COSV68694735; called by muse, mutect2
- SLC8A3 | c.39C>T p.F13= | Silent (SNP) | VAF 33/117 reads (28%) | catalogued as COSV100776309; called by muse, mutect2, varscan2
- TRPM3 | c.1191G>A p.V397= (on ENST00000357533 / NM_001366142.2; = p.V242= on NM_020952.6) | Silent (SNP) | VAF 27/200 reads (14%) | called by muse, mutect2, varscan2
- WDR3 | c.2784G>A p.K928= | Silent (SNP) | VAF 27/141 reads (19%) | called by muse, mutect2, varscan2
- WDR49 | c.576C>T p.N192= (on ENST00000308378 / NM_001366158.1; = p.N533= on NM_001348951.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 42/324 reads (13%) | catalogued as rs372277287; called by muse, mutect2, varscan2
- ZNF234 | c.1149C>T p.Y383= | Silent (SNP) | VAF 27/204 reads (13%) | called by muse, mutect2, varscan2
- ZNF354C | c.1431C>T p.F477= | Silent (SNP) | VAF 18/119 reads (15%) | called by muse, mutect2, varscan2
- ZNF462 | c.2673C>T p.C891= | Silent (SNP) | VAF 42/236 reads (18%) | catalogued as rs1008111986, COSV52951630; called by muse, mutect2, varscan2
- ZXDC | c.384C>T p.A128= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs1012090669; called by muse, mutect2, varscan2
- ABL2 | c.-134C>T | 5'UTR (SNP) | VAF 19/129 reads (15%) | called by muse, mutect2, varscan2
- AGER | c.991+61G>A | Intron (SNP) | VAF 60/390 reads (15%) | catalogued as rs749432309; called by muse, mutect2, varscan2
- AGO3 | c.2474+21G>A | Intron (SNP) | VAF 4/16 reads (25%) | called by mutect2, varscan2
- AK8 | c.*12C>T | 3'UTR (SNP) | VAF 9/97 reads (9%) | called by muse, mutect2
- ALDOC | c.-12-133A>G | Intron (SNP) | VAF 13/31 reads (42%) | called by muse, mutect2, varscan2
- ALKAL2 | c.*337_*339del | 3'UTR (DEL) | VAF 11/67 reads (16%) | called by mutect2, pindel, varscan2
- ARFIP1 | c.*1786A>G | 3'UTR (SNP) | VAF 11/46 reads (24%) | called by muse, mutect2, varscan2
- ARHGEF17 | c.5551-45G>C | Intron (SNP) | VAF 7/26 reads (27%) | called by muse, mutect2, varscan2
- ARRDC2 | c.342-39C>T | Intron (SNP) | VAF 52/163 reads (32%) | called by muse, mutect2, varscan2
- ARSD | c.*1021C>A | 3'UTR (SNP) | VAF 8/19 reads (42%) | called by muse, varscan2
- CACNA1I | c.*1245T>C | 3'UTR (SNP) | VAF 12/71 reads (17%) | called by muse, mutect2, varscan2
- CCDC184 | c.*287C>T | 3'UTR (SNP) | VAF 36/99 reads (36%) | catalogued as rs1263622907; called by muse, mutect2, varscan2
- CCL4L2 | chr17:36210959 C>G | 5'Flank (SNP) | VAF 19/62 reads (31%) | called by muse, mutect2, varscan2
- CHEK1 | c.*27+776C>A | Intron (SNP) | VAF 8/67 reads (12%) | called by muse, mutect2, varscan2
- CHEK1 | c.*27+777T>C | Intron (SNP) | VAF 8/66 reads (12%) | called by muse, mutect2, varscan2
- CHRNB2 | c.*28A>G | 3'UTR (SNP) | VAF 24/220 reads (11%) | called by muse, mutect2, varscan2
- COA5 | c.*180C>T | 3'UTR (SNP) | VAF 43/86 reads (50%) | called by muse, mutect2, varscan2
- CYP11B2 | c.*683C>T | 3'UTR (SNP) | VAF 26/91 reads (29%) | called by muse, mutect2, varscan2
- CYP27B1 | c.964-38C>T | Intron (SNP) | VAF 20/122 reads (16%) | called by muse, mutect2, varscan2
- DPEP3 | c.*77C>T | 3'UTR (SNP) | VAF 38/73 reads (52%) | called by muse, mutect2, varscan2
- E2F2 | c.*3380C>T | 3'UTR (SNP) | VAF 6/124 reads (5%) | called by muse, mutect2
- EDEM1 | c.*1456A>C | 3'UTR (SNP) | VAF 33/133 reads (25%) | called by muse, mutect2, varscan2
- EPB41L4B | c.*99G>A | 3'UTR (SNP) | VAF 28/264 reads (11%) | called by muse, mutect2, varscan2
- EPPIN | c.92-286C>A | Intron (SNP) | VAF 30/79 reads (38%) | called by muse, mutect2, varscan2
- ERBB4 | c.*6117T>A | 3'UTR (SNP) | VAF 11/102 reads (11%) | called by muse, mutect2
- EXOC6B | c.*3062G>T | 3'UTR (SNP) | VAF 4/32 reads (13%) | catalogued as rs866392199; called by muse, varscan2
- FAM13A | c.*2G>A | 3'UTR (SNP) | VAF 5/28 reads (18%) | catalogued as rs761720527; called by muse, mutect2, varscan2
- FHOD1 | c.2202+52G>T | Intron (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2, varscan2
- FNBP1L | c.*564T>C | 3'UTR (SNP) | VAF 19/81 reads (23%) | called by muse, mutect2, varscan2
- FXYD5 | c.-348C>T | 5'UTR (SNP) | VAF 66/177 reads (37%) | called by muse, mutect2, varscan2
- GAD2 | c.*34+604T>C | Intron (SNP) | VAF 16/116 reads (14%) | called by mutect2, varscan2
- GALNT11 | c.587-522C>T | Intron (SNP) | VAF 17/83 reads (20%) | called by muse, mutect2, varscan2
- GBE1 | c.1934+97G>A | Intron (SNP) | VAF 9/67 reads (13%) | called by muse, varscan2
- GNAQ | c.*2243G>A | 3'UTR (SNP) | VAF 26/222 reads (12%) | called by muse, mutect2, varscan2
- GOLPH3L | c.*1569T>A | 3'UTR (SNP) | VAF 5/96 reads (5%) | called by muse, mutect2
- GPRC5A | c.*3934G>C | 3'UTR (SNP) | VAF 28/67 reads (42%) | called by muse, mutect2, varscan2
- GRIN2C | c.*354A>G | 3'UTR (SNP) | VAF 4/60 reads (7%) | catalogued as rs1358648995; called by muse, mutect2
- GRK4 | c.52+2290dup | Intron (INS) | VAF 6/36 reads (17%) | catalogued as rs781483868; called by pindel, varscan2
- GTF3C4 | c.-90G>A | 5'UTR (SNP) | VAF 9/50 reads (18%) | called by muse, mutect2, varscan2
- HAS2 | c.*173C>A | 3'UTR (SNP) | VAF 19/59 reads (32%) | called by muse, mutect2, varscan2
- HECTD4 | c.8400+506G>T | Intron (SNP) | VAF 9/46 reads (20%) | called by muse, mutect2, varscan2
- HERC4 | c.*311C>T | 3'UTR (SNP) | VAF 21/146 reads (14%) | called by muse, mutect2, varscan2
- HPGD | c.94-145G>A | Intron (SNP) | VAF 5/21 reads (24%) | called by muse, mutect2, varscan2
- HPR | c.193+78G>C | Intron (SNP) | VAF 8/39 reads (21%) | called by muse, mutect2
- ITGA8 | c.*550G>A | 3'UTR (SNP) | VAF 8/39 reads (21%) | catalogued as rs1304698621; called by muse, mutect2, varscan2
- KCNA5 | c.*791T>C | 3'UTR (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2
- KCNE4 | c.*64T>C | 3'UTR (SNP) | VAF 36/217 reads (17%) | catalogued as rs1449172454; called by muse, mutect2, varscan2
- KLK6 | c.*53G>A | 3'UTR (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2
- L3MBTL1 | c.1284+797G>A | Intron (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- LDLR | c.*1577C>T | 3'UTR (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2, varscan2
- LPGAT1 | chr1:211745384 G>A | 3'Flank (SNP) | VAF 13/96 reads (14%) | catalogued as rs1363614603; called by muse, mutect2, varscan2
- LRIG3 | c.236+530C>T | Intron (SNP) | VAF 49/115 reads (43%) | called by muse, mutect2, varscan2
- LZTS1 | c.*237A>T | 3'UTR (SNP) | VAF 6/35 reads (17%) | called by muse, mutect2, varscan2
- MCRIP2 | c.413-88C>T | Intron (SNP) | VAF 9/116 reads (8%) | called by muse, mutect2
- MMP14 | c.-111G>T | 5'UTR (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2, varscan2
- MMS19 | c.-8-103C>A | Intron (SNP) | VAF 12/66 reads (18%) | catalogued as rs945077279; called by muse, mutect2, varscan2
- MPZ | c.*576C>T | 3'UTR (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- MSRB1 | c.204+35C>T | Intron (SNP) | VAF 31/85 reads (36%) | catalogued as rs763252841; called by muse, mutect2, varscan2
- MUC3A | c.*331T>A | 3'UTR (SNP) | VAF 25/332 reads (8%) | called by muse, mutect2
- NDUFS1 | c.*2447G>A | 3'UTR (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2, varscan2
- NETO1 | c.469+23660C>G | Intron (SNP) | VAF 49/128 reads (38%) | called by muse, mutect2, varscan2
- NFAM1 | c.*4706G>A | 3'UTR (SNP) | VAF 12/93 reads (13%) | called by muse, mutect2, varscan2
- NFKBIB | chr19:38899952 G>A | 5'Flank (SNP) | VAF 10/76 reads (13%) | called by muse, mutect2, varscan2
- NRXN3 | c.-502C>A | 5'UTR (SNP) | VAF 56/81 reads (69%) | called by muse, mutect2, varscan2
- NXNL2 | c.-129G>A | 5'UTR (SNP) | VAF 18/128 reads (14%) | called by muse, mutect2, varscan2
- OPCML | c.*2907G>A | 3'UTR (SNP) | VAF 10/77 reads (13%) | called by muse, mutect2, varscan2
- PANK3 | c.*41A>G | 3'UTR (SNP) | VAF 20/232 reads (9%) | catalogued as rs931798642; called by muse, mutect2
- PCDH9 | c.*760T>G | 3'UTR (SNP) | VAF 10/51 reads (20%) | called by muse, mutect2, varscan2
- PDE10A | c.*1417G>A | 3'UTR (SNP) | VAF 15/65 reads (23%) | called by muse, mutect2, varscan2
- PDE6A | c.*2878T>G | 3'UTR (SNP) | VAF 18/165 reads (11%) | called by muse, mutect2
- PDS5A | c.*838A>G | 3'UTR (SNP) | VAF 22/101 reads (22%) | called by muse, mutect2, varscan2
- PFKFB4 | c.*327G>T | 3'UTR (SNP) | VAF 10/163 reads (6%) | called by muse, mutect2
- PLA2R1 | c.*1776T>A | 3'UTR (SNP) | VAF 15/81 reads (19%) | called by muse, mutect2, varscan2
- PLD3 | c.*68C>T | 3'UTR (SNP) | VAF 17/140 reads (12%) | called by muse, mutect2, varscan2
- PLOD2 | c.*332A>T | 3'UTR (SNP) | VAF 8/49 reads (16%) | called by muse, mutect2, varscan2
- POFUT2 | c.*528T>G | 3'UTR (SNP) | VAF 7/90 reads (8%) | called by muse, mutect2
- PPP1R1A | c.*411C>T | 3'UTR (SNP) | VAF 20/99 reads (20%) | called by muse, mutect2, varscan2
- PRKAA2 | c.*7213A>G | 3'UTR (SNP) | VAF 34/76 reads (45%) | catalogued as rs971793715; called by muse, mutect2, varscan2
- PRPF40A | c.*1368C>G | 3'UTR (SNP) | VAF 11/50 reads (22%) | called by muse, mutect2, varscan2
- PSAPL1 | c.*2543G>A | 3'UTR (SNP) | VAF 28/158 reads (18%) | catalogued as COSV59843928; called by muse, mutect2, varscan2
- PSCA | c.133+118G>A | Intron (SNP) | VAF 58/160 reads (36%) | catalogued as rs1554638362; called by muse, mutect2, varscan2
- PTGER3 | c.1077+1195G>A | Intron (SNP) | VAF 18/64 reads (28%) | called by muse, mutect2, varscan2
- PTPN3 | c.*1542C>G | 3'UTR (SNP) | VAF 12/138 reads (9%) | catalogued as rs780055293; called by muse, mutect2
- RALGAPA1 | c.*135A>G | 3'UTR (SNP) | VAF 70/171 reads (41%) | catalogued as COSV99353334; called by muse, mutect2, varscan2
- RGS14 | c.*145G>A | 3'UTR (SNP) | VAF 16/135 reads (12%) | catalogued as rs928686303; called by muse, mutect2, varscan2
- RNF130 | c.*368A>T | 3'UTR (SNP) | VAF 10/98 reads (10%) | called by mutect2, varscan2
- RPL7A | c.3+285C>T | Intron (SNP) | VAF 7/58 reads (12%) | called by muse, mutect2, varscan2
- SH2B2 | chr7:102283202 C>T | 5'Flank (SNP) | VAF 13/272 reads (5%) | catalogued as rs1168723684, COSV99475288; called by muse, mutect2
- SHISA6 | c.*36G>A | 3'UTR (SNP) | VAF 18/62 reads (29%) | called by muse, mutect2, varscan2
- SLC10A1 | c.-24G>C | 5'UTR (SNP) | VAF 5/26 reads (19%) | catalogued as rs369686325; called by muse, mutect2, varscan2
- SLC2A10 | c.*2221G>A | 3'UTR (SNP) | VAF 10/81 reads (12%) | called by muse, mutect2, varscan2
- SLCO2A1 | c.*1556C>A | 3'UTR (SNP) | VAF 52/71 reads (73%) | called by muse, mutect2, varscan2
- SMARCB1 | chr22:23835170 ins C | 3'Flank (INS) | VAF 15/96 reads (16%) | called by mutect2, pindel, varscan2
- STARD13 | c.*777G>A | 3'UTR (SNP) | VAF 12/56 reads (21%) | called by muse, mutect2, varscan2
- STX1B | c.*3216G>T | 3'UTR (SNP) | VAF 31/78 reads (40%) | called by muse, mutect2, varscan2
- SYCE1 | chr10:133567833 A>T | 5'Flank (SNP) | VAF 5/33 reads (15%) | called by muse, mutect2, varscan2
- TEKT1 | c.*1853A>T | 3'UTR (SNP) | VAF 16/98 reads (16%) | called by muse, mutect2, varscan2
- THUMPD2 | c.*149C>T | 3'UTR (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2
- TSPAN18 | c.-10-8620G>A | Intron (SNP) | VAF 50/268 reads (19%) | called by muse, mutect2, varscan2
- VPS45 | chr1:150067783 G>A | 5'Flank (SNP) | VAF 28/113 reads (25%) | catalogued as rs1418338148; called by muse, mutect2, varscan2
- WIPF2 | c.*2367G>A | 3'UTR (SNP) | VAF 14/52 reads (27%) | called by muse, mutect2, varscan2
- WNT5A | c.*324T>G | 3'UTR (SNP) | VAF 25/77 reads (32%) | called by muse, mutect2, varscan2
- XAB2 | c.-12G>A | 5'UTR (SNP) | VAF 51/341 reads (15%) | called by muse, mutect2, varscan2
- XKR4 | c.806+58184G>A | Intron (SNP) | VAF 20/92 reads (22%) | called by muse, mutect2, varscan2
- ZDHHC9 | c.*601T>C | 3'UTR (SNP) | VAF 70/82 reads (85%) | called by muse, mutect2, varscan2
- ZFP37 | c.*2281T>G | 3'UTR (SNP) | VAF 16/89 reads (18%) | called by muse, mutect2, varscan2
- ZIC1 | c.*1460C>T | 3'UTR (SNP) | VAF 11/65 reads (17%) | called by muse, mutect2, varscan2
- ZNF449 | c.354+697G>A | Intron (SNP) | VAF 14/74 reads (19%) | called by muse, mutect2, varscan2
- ZNF658B | n.198G>T | RNA (SNP) | VAF 5/92 reads (5%) | called by muse, mutect2
- ZNF829 | c.*3102A>T | 3'UTR (SNP) | VAF 50/181 reads (28%) | called by muse, mutect2, varscan2
- ZNF971P | n.1033C>T | RNA (SNP) | VAF 53/204 reads (26%) | called by muse, mutect2, varscan2
